Gene-level copy-number profile of tumor specimen TCGA-R2-A69V-01A from TCGA case TCGA-R2-A69V, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, large cell, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB; Tumor grade: G3; Age at diagnosis: 42.4 years (15,479 days).
Specimen TCGA-R2-A69V-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-CESC.fb03a12d-6050-49b1-86df-3c6a02b3421f.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-R2-A69V-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/94a15558-2613-4f2e-926d-f81a4b75f22e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 80; copy number 1: 8,396; copy number 2: 34,624; copy number 3: 14,710; copy number 4: 1,232; copy number 5: 76; copy number 6: 701.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-R2-A69V-01A-11D-A32H-01): tumor purity 0.24, ploidy 2.28, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 68 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:22,066,016–22,509,406, 68 genes (within-gene range 0–2) (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 777 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:17,790,761–23,470,491, 76 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr8:53,712,697–86,321,146, 503 genes, copy number 6 (broad region; genes not listed).
- chr8:140,591,684–145,066,685, 198 genes, copy number 6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 7,582. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
